Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3BZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3BZ-06A (Metastatic).

DIAGNOSIS

Patient ID - Sample ID

(A) LEFT UPPER NECK:
Scar, biopsied.

(B) LEFT MODIFIED RADICAL NECK DISSECTION:
MALIGNANT MELANOMA METASTATIC ONE OF FORTY-THREE LYMPH NODES (1/43).
THE LARGEST TUMOR SIZE 80.0 X 70.0 MM.
EXTRACAPSULAR EXTENSION PRESENT.
(DISSECTION: ZERO OF FOUR NODES LEVEL 2, TWO OF TWELVE NODES LEVEL 3, THREE OF TWENTY NODES
LEVEL 4, ZERO OF SEVEN LEVEL 5).

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) INCISIONAL SCAR, LEFT UPPER NECK - A white-tan non-oriented irregular fragment of skin, 5.6 x 0.9 x 0.7 cm. There is a healed scar, approximately 3.1 cm long, on the surface of the specimen. The specimen is serially sectioned and representative sections are submitted in A1 and A2. AS1/mmc

(B) LEFT MODIFIED RADICAL NECK DISSECTION - A 17.0 x 11.0 x 5.0 cm portion of adipose tissue and skeletal muscle oriented by the surgeon (levels 2, 3, 4, and 5).

An 8.0 x 7.0 x 5.5 cm mass is present between levels 2 and 3. The mass is black, tarry, and necrotic. The wall of the mass is fibrotic and varies in thickness from 0.4 to 1.0 cm.

Multiple lymph nodes are identified ranging in size from 0.3-1.8 cm in maximum dimension. A submandibular gland is located in level 2 measuring 3.7 x 3.5 x 2.5 cm.

Representative material from the tumor is submitted to the tissue bank.

SECTION CODE: B1-B7, level 2 (B1, B2, black mass; B3, single bisected lymph node; B4, multiple intact lymph nodes; B5, submandibular gland; B6, B7, single bisected lymph node in each); B8-B15, level 3 (B8-B11, black tarry mass with fibrous capsule; B12, multiple intact lymph nodes; B13, multiple intact lymph nodes; B14, single bisected lymph node; B15, multiple intact lymph nodes); B16-B20, multiple intact lymph nodes, level 4; B21, single bisected lymph node, level 5; B22, B23, multiple intact lymph node, level 5.

CLINICAL HISTORY

None given.

SNOMED CODES

T-C4000, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 24bf210c-40b8-4810-97e5-44271ed41402 (TCGA-D3-A3BZ.968FCFF6-6D7A-48F2-BC66-F9F7E61B095D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).